Somatic mutation profile of tumor specimen MP2PRT-PARHDU-TMP1-A (aliquot MP2PRT-PARHDU-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARHDU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 5.7 years (2,087 days).
Specimen MP2PRT-PARHDU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a54ecbe-b64f-40df-b739-798bb8e64ea3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARHDU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARHDU-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1077cc8-13b9-4cc6-85ec-b69f214423ee

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP46 | c.1114G>A p.V372M | Missense Mutation (SNP) | VAF 232/534 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as rs752527145, COSV63952068; called by muse, varscan2
- DDR1 | c.2423G>A p.R808H (on ENST00000324771; = p.R771H on NM_001954.4) | Missense Mutation (SNP) | VAF 219/520 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1045387235; called by muse, varscan2
- HYDIN | c.8875C>T p.R2959C | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs770307678, COSV99992168; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 166/376 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPP1R26 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 140/361 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs375453673; called by muse, mutect2, varscan2
- SYNE1 | c.4928C>T p.A1643V (on ENST00000367255 / NM_182961.4; = p.A1650V on NM_033071.3) | Missense Mutation (SNP) | VAF 113/271 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as rs753598584, COSV54943251, COSV55051913; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF226 | c.53C>T p.T18M | Missense Mutation (SNP) | VAF 81/172 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs756751752, COSV56197568; called by muse, mutect2, varscan2
- SORCS3 | c.2470C>A p.L824I | Missense Mutation (SNP) | VAF 172/407 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, varscan2
- TPP2 | c.404A>G p.E135G | Missense Mutation (SNP) | VAF 86/222 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, varscan2
- FARP1 | c.2511C>T p.A837= | Silent (SNP) | VAF 180/476 reads (38%) | catalogued as rs139091102; called by muse, varscan2
